Somatic mutation profile of tumor specimen 0DN1D6 from CCDI case PBCBBX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (839 days).
Specimen 0DN1D6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31b8b1f9-1e4e-4613-9bd6-b369339e4d7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59257222-83f4-4c3a-ad17-eafa6d490f13

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EVC2 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 276/1000 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs745640603, COSV60397522; called by muse, mutect2, varscan2
- FAM47C | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 40/1278 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs138293293, COSV100792387, COSV100792939; called by muse, mutect2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 68/1890 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2
- RNF113A | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 182/706 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs768022410; called by muse, mutect2, varscan2
- MROH5 | c.600G>A p.S200= | Silent (SNP) | VAF 74/1034 reads (7%) | catalogued as rs369438497; called by muse, mutect2
- SLC6A5 | c.558T>C p.D186= | Silent (SNP) | VAF 34/1093 reads (3%) | called by muse, mutect2
- CRCT1 | c.-3G>A | 5'UTR (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
